Gene-level copy-number profile of tumor specimen ALCH-AFFH-TTP1-A from ALCHEMIST case ALCH-AFFH, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.8 years (25,499 days).
Specimen ALCH-AFFH-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e89aa143-f9d8-4b18-85d8-52cb04679869.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AFFH-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/f8f9c0c9-63a1-49d1-a434-c6a4efce5238

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 13,601; copy number 2: 41,466; copy number 3: 3,706; copy number 4: 124.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:57,941,818–57,942,304, 1 gene: PPIAP16.
- chr16:75,192,465–75,193,247, 1 gene: AC009078.1.
- chr19:29,811,991–29,824,312, 1 gene: CCNE1.
- chr22:15,282,557–15,350,043, 5 genes: AP000542.3, AP000542.1, AP000542.2, ZNF72P, BNIP3P2.
- chr22:20,299,760–20,320,080, 3 genes: AC007663.1, DGCR6L, AC007663.4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 10,830. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
